Somatic mutation profile of tumor specimen TCGA-AZ-4682-01B (aliquot TCGA-AZ-4682-01B-01D-1408-10) from TCGA case TCGA-AZ-4682, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Age at diagnosis: 61.4 years (22,409 days).
Specimen TCGA-AZ-4682-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b61f48c3-3918-40f7-9ffb-7e7a82d7b368.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-4682-10A (Blood Derived Normal), aliquot TCGA-AZ-4682-10A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dc28aa0-47fd-4ac9-be66-e60459084da9

The open-access MAF lists 94 somatic variants for this specimen: 65 protein-altering or splice-affecting, 24 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 24, Nonsense Mutation 6, RNA 3, Intron 2, Frame Shift Del 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 29/53 reads (55%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs530929710, COSV51711966; called by muse, mutect2, varscan2
- ACTRT1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 62/78 reads (79%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs749902150, COSV64419079; called by muse, mutect2, varscan2
- AGFG1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV59512722; called by muse, mutect2, varscan2
- APIP | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV53507290; called by muse, mutect2, varscan2
- ARHGAP39 | c.2270G>A p.R757Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs778343992, COSV52771568; called by muse, mutect2, varscan2
- ATMIN | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55146093, COSV55146511; called by muse, mutect2, varscan2
- CAMK2G | c.1516G>A p.A506T (on ENST00000423381 / NM_001367518.1; = p.A443T on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1441246179, COSV55215547; called by muse, mutect2, varscan2
- CDH8 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as rs375557193; called by muse, mutect2, varscan2
- CFAP161 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as rs747943731, COSV54429582, COSV54429974; called by muse, mutect2, varscan2
- CHST6 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1381630371, COSV60000675; called by muse, mutect2, varscan2
- DCT | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375600704; called by muse, mutect2, varscan2
- DOCK3 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); catalogued as COSV56528149; called by muse, mutect2, varscan2
- DSCAM | c.6016G>A p.A2006T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs781716602, COSV68028967; called by muse, mutect2, varscan2
- DYNC2H1 | c.6532C>T p.H2178Y | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as rs1453286639, COSV100519032, COSV62096612; called by muse, mutect2, varscan2
- EPHA5 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56647169, COSV99897569; called by muse, mutect2, varscan2
- ESRP2 | c.1103C>T p.S368L (on ENST00000565858 / NM_001365264.1; = p.S358L on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.322); catalogued as rs763741902, COSV52174036; called by muse, mutect2, varscan2
- GFI1 | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs777241871, COSV54041845; ClinVar: likely benign; called by muse, mutect2, varscan2
- HAGH | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772821746, COSV68400701; called by muse, mutect2, varscan2
- HAO1 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1431748352, COSV66492371; called by muse, mutect2, varscan2
- HLCS | c.2146A>T p.M716L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV51769817; called by muse, mutect2, varscan2
- KAT6A | c.5668G>A p.A1890T | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766320012, COSV55906578, COSV55913613; called by muse, mutect2, varscan2
- KCND3 | c.899T>A p.F300Y | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as COSV56182585; called by muse, mutect2, varscan2
- KRT14 | c.218T>A p.F73Y | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51421696; called by muse, mutect2
- KRT6A | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747115156, COSV100416602, COSV58105712; called by muse, mutect2, varscan2
- LIFR | c.2525T>A p.I842N | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54692037; called by muse, mutect2, varscan2
- MGAT4B | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs781520422, COSV52978236; called by muse, mutect2, varscan2
- MIDN | c.282C>A p.S94R | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56295417; called by muse, mutect2, varscan2
- MYO18B | c.5857G>A p.E1953K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as rs374817192, COSV59137393; called by muse, mutect2, varscan2
- NALCN | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 175/270 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs569850296, COSV51915517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAPG2 | c.1514T>G p.V505G | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV51988632; called by muse, varscan2
- NID1 | c.3578C>T p.T1193I | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV51622048; called by muse, mutect2, varscan2
- NMNAT2 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.875); catalogued as rs760875625, COSV54269187; called by muse, mutect2, varscan2
- NUP205 | c.3676G>A p.V1226I | Missense Mutation (SNP) | VAF 106/183 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs776788224, COSV53660726; called by muse, mutect2, varscan2
- NUP98 | c.2320T>C p.S774P | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61433557; called by muse, mutect2, varscan2
- OR52M1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs529200501, COSV64172160; called by muse, mutect2, varscan2
- OR8G1 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100422317; called by mutect2, varscan2
- PCDHB6 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV50718092; called by muse, mutect2, varscan2
- PDCD7 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs945024622, COSV52600638; called by muse, mutect2, varscan2
- POLM | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs142658845; called by muse, mutect2, varscan2
- POTEA | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs767546235; called by muse, mutect2, varscan2
- POU3F3 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV63721905; called by muse, mutect2, varscan2
- PPP3CA | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV59922825, COSV59932721; called by muse, mutect2, varscan2
- PRKG2 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs187350442; called by muse, mutect2, varscan2
- RANBP6 | c.2930C>T p.T977I | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99424052, COSV99424281; called by muse, mutect2, varscan2
- RYR2 | c.11146G>A p.E3716K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV63676833; called by muse, mutect2, varscan2
- SIGLEC8 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV58474288; called by mutect2, varscan2
- SLC35A5 | c.926T>G p.L309R | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53727103; called by muse, mutect2, varscan2
- SNAPC4 | c.810C>T p.N270= | Splice Region (SNP) | VAF 5/18 reads (28%) | catalogued as rs201465171, COSV100046973; called by muse, mutect2, varscan2
- TAF4 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs1329345367, COSV53334712; called by muse, mutect2
- TLR9 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs988141890, COSV62347200; called by muse, mutect2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs754390908; called by mutect2, varscan2
- TMEM184A | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769628960, COSV52475346; called by muse, mutect2, varscan2
- TRIML2 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV58717127; called by muse, mutect2, varscan2
- TULP4 | c.4396G>T p.V1466L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV65576684; called by muse, mutect2, varscan2
- UBASH3B | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs368713247, COSV52496439; called by muse, mutect2, varscan2
- USP9X | c.6564A>T p.L2188F | Missense Mutation (SNP) | VAF 65/73 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV100200302, COSV61070587; called by muse, mutect2, varscan2
- USP9X | c.7008T>A p.Y2336* | Nonsense Mutation (SNP) | VAF 135/159 reads (85%) | catalogued as COSV100198769; called by muse, mutect2, varscan2
- YBEY | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59309535, COSV59310316; called by muse, mutect2
- ZGRF1 | c.4016T>G p.L1339R | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.043); catalogued as rs535903637, COSV58409344; called by muse, mutect2, varscan2
- ABCA7 | c.3937C>T p.H1313Y | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- NLN | c.766_768del p.C256del | In Frame Del (DEL) | VAF 13/55 reads (24%) | called by pindel, varscan2
- TMEM72 | c.613del p.L205* | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- ZNF676 | c.854A>G p.Y285C (on ENST00000650058; = p.Y253C on NM_001001411.3) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- ATF2 | c.132C>T p.V44= | Silent (SNP) | VAF 35/46 reads (76%) | catalogued as COSV51370245; called by muse, mutect2, varscan2
- CACNA1B | c.4839C>T p.Y1613= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs200847209, COSV53130916; called by muse, mutect2, varscan2
- CACNA2D3 | c.1707C>T p.D569= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs758954184, COSV55548148; called by muse, mutect2, varscan2
- CHAF1B | c.1101C>T p.D367= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs200643242, COSV58439452; called by muse, mutect2, varscan2
- COL11A2 | c.4494C>T p.G1498= (on ENST00000341947 / NM_080680.3; = p.G1391= on NM_080679.2) | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs576235181, COSV100553990, COSV59498722; called by muse, mutect2, varscan2
- DAAM2 | c.3084G>A p.S1028= (on ENST00000274867 / NM_001201427.2; = p.S1027= on NM_015345.3) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs773772935, COSV51337104; called by muse, mutect2, varscan2
- GLRA3 | c.939C>G p.V313= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs759857592, COSV56863553; called by mutect2, varscan2
- GRIA2 | c.213C>T p.F71= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs746340381, COSV52394007; called by muse, mutect2, varscan2
- LIFR | c.2526C>A p.I842= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as COSV54692012; called by muse, mutect2, varscan2
- MACROD2 | c.1077G>A p.E359= (on ENST00000642719; = p.E331= on NM_080676.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as COSV53988382, COSV53999118; called by muse, mutect2, varscan2
- NACA2 | c.51G>A p.P17= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs779669551, COSV71713140; called by muse, mutect2, varscan2
- NCR2 | c.43C>T p.L15= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- OR2G6 | c.696G>A p.A232= | Silent (SNP) | VAF 50/155 reads (32%) | catalogued as rs755014909, COSV58574856; called by muse, mutect2, varscan2
- PCDHA2 | c.1353C>T p.N451= | Silent (SNP) | VAF 59/147 reads (40%) | catalogued as rs376199248; called by muse, mutect2, varscan2
- PKHD1L1 | c.8130C>T p.V2710= | Silent (SNP) | VAF 45/164 reads (27%) | catalogued as rs770989608, COSV65745274; called by muse, mutect2, varscan2
- POLR3E | c.1518C>T p.G506= | Silent (SNP) | VAF 79/196 reads (40%) | catalogued as rs139910117; called by muse, mutect2, varscan2
- SGSH | c.1365G>A p.P455= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs750709138, COSV58339482; called by muse, mutect2, varscan2
- SOX11 | c.310C>A p.R104= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as rs1388465829, COSV100430658, COSV58985912; called by muse, mutect2, varscan2
- SRGAP1 | c.1224A>G p.T408= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100754801, COSV61899276; called by muse, mutect2, varscan2
- STAB2 | c.3096C>T p.L1032= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as rs780980945, COSV66340837; called by muse, mutect2, varscan2
- STPG2 | c.867T>C p.S289= | Silent (SNP) | VAF 57/142 reads (40%) | catalogued as COSV54802722; called by muse, mutect2, varscan2
- THNSL1 | c.483A>C p.L161= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV64479452; called by muse, mutect2, varscan2
- ZNF34 | c.186C>T p.D62= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs759237384, COSV58639277; called by muse, mutect2, varscan2
- ZNF575 | c.579C>T p.A193= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs199586447, COSV100045365; called by muse, mutect2, varscan2
- FAM74A3 | n.173G>A | RNA (SNP) | VAF 122/320 reads (38%) | called by muse, mutect2, varscan2
- MIR514A2 | n.80G>A | RNA (SNP) | VAF 63/190 reads (33%) | catalogued as rs782190348; called by mutect2, varscan2
- MIR514A3 | n.80G>A | RNA (SNP) | VAF 37/279 reads (13%) | catalogued as rs782208789; called by mutect2, varscan2
- RFX4 | c.378-2063G>T | Intron (SNP) | VAF 19/46 reads (41%) | catalogued as COSV57576844; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1810T>C | Intron (SNP) | VAF 118/326 reads (36%) | catalogued as rs777985848, COSV62467085; called by muse, mutect2, varscan2
